CCDI case PBCBNP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/24c3143a-577e-4eca-8829-f635f2405ab8

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.5 years (3,823 days).

Biospecimens (3 samples)
- Sample 0DRZIG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRZIS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRZJB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
